Somatic mutation profile of tumor specimen TCGA-61-2018-01A (aliquot TCGA-61-2018-01A-01W-0722-08) from TCGA case TCGA-61-2018, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 62.8 years (22,929 days).
Specimen TCGA-61-2018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7abe10cb-71f9-40b5-8582-8d2f7341890d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2018-11A (Solid Tissue Normal), aliquot TCGA-61-2018-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c81d837b-f931-44f8-b6ab-9efb4483968f

The open-access MAF lists 86 somatic variants for this specimen: 69 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Nonsense Mutation 10, 3'UTR 1, Intron 1, 5'Flank 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT2 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99469163; called by muse, mutect2, varscan2
- ADGRB3 | c.4348A>T p.R1450* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV99486425; called by muse, mutect2, varscan2
- ANK1 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as COSV55897845; called by muse, mutect2, varscan2
- AOX1 | c.3151G>T p.V1051F | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99613749; called by muse, mutect2, varscan2
- ARHGEF6 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51697215, COSV99166598; called by muse, mutect2
- BANF1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100381408; called by muse, mutect2, varscan2
- CCAR1 | c.188T>A p.L63* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as rs902788504, COSV99771295; called by muse, mutect2, varscan2
- CD109 | c.3650C>A p.P1217H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99754282; called by muse, mutect2, varscan2
- CDH2 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 31/433 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV52278837, COSV99297977; called by muse, mutect2
- CEP162 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as COSV100003172; called by muse, mutect2
- CHD4 | c.4291C>A p.L1431I (on ENST00000357008 / NM_001363606.2; = p.L1444I on NM_001273.5) | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100538788; called by muse, mutect2, varscan2
- CLINT1 | c.1571G>T p.G524V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV99754493; called by muse, mutect2, varscan2
- COL3A1 | c.3382G>T p.G1128C | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483573; called by muse, mutect2
- COL5A1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs370311038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.2603C>A p.T868K (on ENST00000520002; = p.T867K on NM_033225.6) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV100152200, COSV100156101; called by muse, mutect2, varscan2
- CXorf66 | c.1011C>A p.D337E | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.389); catalogued as COSV100983924; called by muse, mutect2, varscan2
- DDX47 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 194/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1444843568, COSV100774618; called by muse, mutect2, varscan2
- DIXDC1 | c.1003C>A p.Q335K (on ENST00000440460 / NM_001037954.4; = p.Q124K on NM_033425.4) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100180397; called by muse, mutect2
- DNAH9 | c.12571A>T p.T4191S | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV99307328; called by muse, mutect2, varscan2
- DPYS | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs367706394; called by muse, mutect2, varscan2
- DUOX1 | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99973431; called by muse, mutect2
- DUOX1 | c.1748T>C p.V583A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100368316; called by muse, mutect2
- EMILIN2 | c.1007A>T p.K336M | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99598775; called by muse, mutect2
- ENTPD3 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100088943; called by muse, mutect2, varscan2
- FAM153B | c.726G>C p.E242D (on ENST00000253490; = p.E165D on NM_001265615.1) | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.402); catalogued as rs750639998, COSV99499050; called by muse, mutect2
- FAM153B | c.727G>T p.E243* (on ENST00000253490; = p.E166* on NM_001265615.1) | Nonsense Mutation (SNP) | VAF 40/439 reads (9%) | catalogued as COSV99499052; called by muse, mutect2
- FAM3C | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100739905; called by muse, mutect2
- FAT3 | c.12660C>G p.N4220K | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99969007; called by muse, mutect2
- FAT4 | c.3491A>G p.E1164G | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101272589; called by muse, mutect2, varscan2
- FN1 | c.5977G>T p.E1993* | Nonsense Mutation (SNP) | VAF 29/153 reads (19%) | catalogued as COSV100117886, COSV60550006; called by muse, mutect2, varscan2
- GRIA4 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 21/183 reads (11%) | catalogued as COSV99233647; called by muse, mutect2, varscan2
- GRIN2A | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100410676; called by muse, varscan2
- IGFN1 | c.3517G>A p.E1173K (on ENST00000295591 / NM_001367841.1; = p.E3630K on NM_001164586.2) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375211075, COSV99813399; called by muse, mutect2, varscan2
- INTS14 | c.514C>T p.L172F (on ENST00000313182 / NM_001366360.2; = p.L93F on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV100500059, COSV57528889; called by muse, mutect2, varscan2
- ITGA5 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99516860; called by muse, mutect2, varscan2
- KIAA1217 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 76/425 reads (18%) | catalogued as COSV100287045, COSV56813039; called by muse, mutect2, varscan2
- KMT2A | c.4742A>G p.Y1581C | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as rs1565293702, COSV100629471; called by muse, mutect2, varscan2
- LRRC2 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99947588; called by muse, mutect2, varscan2
- MARK2 | c.898A>C p.K300Q | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100159029; called by muse, mutect2, varscan2
- MMP10 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.479); catalogued as COSV99666694; called by muse, mutect2
- MRPL14 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs537621553, COSV64394618; called by muse, mutect2, varscan2
- OR10C1 | c.133C>T p.L45F (on ENST00000622521; = p.L43F on NM_013941.3) | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV101010878; called by muse, mutect2, varscan2
- OVCH1 | c.2365G>T p.V789F | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100549024; called by muse, mutect2, varscan2
- P2RX6 | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.253); catalogued as COSV100298823; called by muse, mutect2, varscan2
- PAMR1 | c.1486G>A p.E496K (on ENST00000619888 / NM_001001991.3; = p.E513K on NM_015430.4) | Missense Mutation (SNP) | VAF 159/458 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs924381135, COSV99553042; called by muse, mutect2, varscan2
- PARP4 | c.1632G>C p.E544D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101131929; called by muse, mutect2
- PBRM1 | c.646-1G>T p.X216_splice | Splice Site (SNP) | VAF 24/285 reads (8%) | catalogued as COSV99970250; called by muse, mutect2
- PLCG2 | c.2302T>C p.S768P | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.558); catalogued as COSV100842528; called by muse, mutect2, varscan2
- PLEKHM1 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV101378840; called by muse, mutect2
- PNLDC1 | c.187T>G p.F63V | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99277742; called by muse, mutect2, varscan2
- PNMA3 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1269935119, COSV64723077; called by muse, mutect2, varscan2
- PRPF3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV100255043; called by muse, varscan2
- RFX3 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV100175597; called by muse, mutect2, varscan2
- RING1 | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV100761832; called by muse, mutect2, varscan2
- SLC25A40 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs146277655; called by muse, mutect2
- SMC3 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100700008; called by muse, mutect2, varscan2
- TACC2 | c.3127G>T p.A1043S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100553345; called by muse, mutect2
- TADA3 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99809594; called by muse, mutect2, varscan2
- TMEM67 | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 135/494 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.087); catalogued as rs374231895; called by muse, mutect2, varscan2
- TNFRSF21 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 212/415 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99730072; called by muse, mutect2, varscan2
- TP53 | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 158/250 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1453167097, COSV52662137, COSV52723150, COSV52965616, COSV53563961; called by muse, mutect2, varscan2
- TTF1 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 10/270 reads (4%) | catalogued as COSV100524824; called by muse, mutect2
- VDAC1 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV99527302; called by muse, mutect2
- VPS13C | c.3854A>T p.N1285I (on ENST00000644861 / NM_020821.3; = p.N1242I on NM_017684.5) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs771334380, COSV99829700; called by muse, mutect2, varscan2
- ABCC12 | c.987_989del p.R331del | In Frame Del (DEL) | VAF 368/486 reads (76%) | called by pindel, varscan2
- ANXA8 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAM153A | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- MDFI | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SPTAN1 | c.5199_5227del p.Q1734Rfs*19 | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | called by mutect2, pindel, varscan2
- CCDC65 | c.444C>G p.A148= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99908177; called by muse, mutect2, varscan2
- FOXJ3 | c.1710T>C p.P570= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100692107; called by muse, varscan2
- HPS1 | c.1921C>T p.L641= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100282757; called by muse, mutect2, varscan2
- HSD17B7 | c.369G>C p.L123= | Silent (SNP) | VAF 69/235 reads (29%) | catalogued as rs1267294616, COSV99597787; called by muse, mutect2, varscan2
- MIOS | c.402T>C p.D134= | Silent (SNP) | VAF 40/329 reads (12%) | catalogued as COSV100402912; called by muse, mutect2, varscan2
- NCAPH | c.2146C>T p.L716= | Silent (SNP) | VAF 101/309 reads (33%) | catalogued as rs147238606; called by muse, mutect2, varscan2
- PLSCR1 | c.564C>T p.C188= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs756026114, COSV100678440; called by muse, mutect2, varscan2
- PRICKLE1 | c.1248G>A p.T416= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs142502371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF10 | c.291T>C p.P97= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100378875; called by muse, varscan2
- SRRM3 | c.264G>A p.V88= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100418830; called by muse, mutect2
- WNK1 | c.7143C>G p.T2381= (on ENST00000315939 / NM_018979.4; = p.T2133= on NM_014823.3) | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs369472011, COSV99942661; called by muse, mutect2, varscan2
- ZEB2 | c.237G>A p.L79= | Silent (SNP) | VAF 87/440 reads (20%) | catalogued as COSV100356609; called by muse, mutect2, varscan2
- ZNF142 | c.2436G>A p.Q812= (on ENST00000411696 / NM_001379660.1; = p.Q612= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV101376976; called by muse, mutect2, varscan2
- ZNF557 | c.180G>C p.L60= (on ENST00000414706 / NM_001044388.2; = p.L67= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/290 reads (9%) | catalogued as COSV99422671; called by muse, mutect2
- ADD2 | c.1742-242A>C | Intron (SNP) | VAF 40/170 reads (24%) | catalogued as COSV100036235; called by muse, mutect2, varscan2
- FBXO48 | c.*1G>T | 3'UTR (SNP) | VAF 20/266 reads (8%) | called by mutect2, varscan2
- HOXD4 | chr2:176150354 G>T | 5'Flank (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
